Somatic mutation profile of tumor specimen TCGA-EY-A1GO-01A (aliquot TCGA-EY-A1GO-01A-11D-A14G-09) from TCGA case TCGA-EY-A1GO, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC1; Tumor grade: G2; Age at diagnosis: 65.3 years (23,853 days).
Specimen TCGA-EY-A1GO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b05a6097-f8bd-40a3-869d-1dca3e636a00.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EY-A1GO-10A (Blood Derived Normal), aliquot TCGA-EY-A1GO-10A-01D-A14G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/60a91db6-f8fb-431a-a86a-796f2da6b35f

The open-access MAF lists 354 somatic variants for this specimen: 253 protein-altering or splice-affecting, 93 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 186, Silent 93, Frame Shift Del 39, Nonsense Mutation 12, Frame Shift Ins 9, RNA 4, Intron 3, Splice Site 3, Splice Region 2, In Frame Ins 1, In Frame Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.11093del p.G3698Afs*51 | Frame Shift Del (DEL) | VAF 6/70 reads (9%) | catalogued as rs35493001; ClinVar: pathogenic; called by mutect2, pindel
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 50/52 reads (96%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- OFD1 | c.710del p.K237Sfs*6 | Frame Shift Del (DEL) | VAF 18/73 reads (25%) | catalogued as rs312262845; ClinVar: pathogenic; called by mutect2, varscan2
- RARB | c.865G>A p.G289S (on ENST00000383772 / NM_001290216.2; = p.G282S on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/35 reads (86%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1553637463, COSV51972080; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SLC16A1 | c.41del p.P14Qfs*10 | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | catalogued as rs606231309; ClinVar: pathogenic; called by mutect2, varscan2
- SMPX | c.99del p.R34Efs*47 | Frame Shift Del (DEL) | VAF 13/60 reads (22%) | catalogued as rs398122930, CD130105; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- AAAS | c.1586A>G p.D529G | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.373); catalogued as rs1285653146, COSV99266960; called by muse, mutect2
- ABCA8 | c.4155+1G>T p.X1385_splice | Splice Site (SNP) | VAF 18/107 reads (17%) | catalogued as COSV52203900; called by muse, mutect2, varscan2
- ACACB | c.4783A>G p.N1595D | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100622860; called by muse, mutect2, varscan2
- ACAD8 | c.1199G>A p.S400N | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as COSV99844317; called by muse, mutect2, varscan2
- ACTRT2 | c.1005del p.D336Tfs*16 | Frame Shift Del (DEL) | VAF 22/67 reads (33%) | catalogued as rs1159784582; called by mutect2, pindel, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 16/99 reads (16%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- AGAP4 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 69/379 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1289763348, COSV101432651; called by muse, mutect2, varscan2
- ANK1 | c.2942C>T p.T981M | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs767717861, COSV99225189; called by muse, mutect2, varscan2
- ANO9 | c.1333A>G p.R445G | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV60449152; called by muse, mutect2, varscan2
- ANXA6 | c.1106C>T p.A369V | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.924); catalogued as COSV100636905; called by muse, mutect2, varscan2
- ARHGAP45 | c.3397C>T p.P1133S | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.709); catalogued as COSV99297540; called by muse, mutect2, varscan2
- ATP10D | c.1848del p.L617Cfs*41 | Frame Shift Del (DEL) | VAF 9/54 reads (17%) | catalogued as rs764067652, COSV56705401; called by mutect2, pindel, varscan2
- ATP1B4 | c.661C>T p.Q221* (on ENST00000218008 / NM_001142447.3; = p.Q217* on NM_012069.5) | Nonsense Mutation (SNP) | VAF 21/58 reads (36%) | catalogued as COSV99486334; called by muse, mutect2, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 13/42 reads (31%) | catalogued as rs768244116; called by mutect2, pindel, varscan2
- BIN1 | c.167C>T p.T56M | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs758360325, COSV99035052; called by muse, varscan2
- BRD2 | c.467A>G p.N156S | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100875672; called by muse, mutect2, varscan2
- BRPF1 | c.1139C>T p.A380V | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100121248; called by muse, mutect2
- C17orf97 | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.005); catalogued as rs782124924, COSV100789337; called by muse, mutect2, varscan2
- C1QL3 | c.529G>A p.V177I | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.572); catalogued as COSV100126913; called by muse, mutect2, varscan2
- C2orf78 | c.1364del p.P455Rfs*28 | Frame Shift Del (DEL) | VAF 8/47 reads (17%) | catalogued as COSV68517668; called by mutect2, pindel, varscan2
- CACUL1 | c.165dup p.Q56Afs*30 | Frame Shift Ins (INS) | VAF 14/53 reads (26%) | catalogued as rs747095390; called by mutect2, varscan2
- CAPZA2 | c.300C>G p.H100Q | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100753908; called by muse, mutect2, varscan2
- CARD6 | c.2654T>C p.L885P | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV99620784; called by muse, mutect2
- CBLN3 | c.265G>A p.G89S | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199897938, COSV52159925; called by muse, mutect2, varscan2
- CBY2 | c.752G>T p.R251L | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as COSV100137592, COSV60117052; called by muse, mutect2, varscan2
- CCDC74B | c.809C>T p.T270I | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100134446; called by muse, mutect2
- CCDC88C | c.3410C>T p.T1137M | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs1173847504, COSV66233428; called by muse, mutect2, varscan2
- CCR7 | c.625C>T p.R209* | Nonsense Mutation (SNP) | VAF 10/43 reads (23%) | catalogued as rs1463167209, COSV55851192; called by muse, mutect2, varscan2
- CD1A | c.848G>T p.S283I | Missense Mutation (SNP) | VAF 95/113 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99192354; called by muse, mutect2, varscan2
- CDC14A | c.375del p.Y126Ifs*64 | Frame Shift Del (DEL) | VAF 27/75 reads (36%) | catalogued as rs773911500; called by mutect2, pindel, varscan2
- CDH11 | c.2314C>A p.L772I | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1314421886, COSV99218305; called by muse, mutect2, varscan2
- CDH12 | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV101202483, COSV66439190; called by muse, mutect2, varscan2
- CDK5R1 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as COSV99912461; called by muse, mutect2, varscan2
- CDK8 | c.139A>G p.K47E | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.297); catalogued as COSV101037228; called by muse, mutect2, varscan2
- CELSR1 | c.1393G>A p.V465M | Missense Mutation (SNP) | VAF 9/151 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); catalogued as COSV99418219; called by muse, mutect2
- CEP72 | c.1100T>C p.L367P | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.96); catalogued as COSV99374759; called by muse, mutect2
- CFAP300 | c.796A>G p.M266V | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV101462459; called by muse, mutect2
- CHD8 | c.5453A>G p.D1818G (on ENST00000646647 / NM_001170629.2; = p.D1539G on NM_020920.4) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs371906576, COSV100765301; called by muse, mutect2, varscan2
- CHD8 | c.1388G>A p.R463Q (on ENST00000646647 / NM_001170629.2; = p.R184Q on NM_020920.4) | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1224928579, COSV101303134; called by muse, mutect2, varscan2
- CHRM3 | c.1700dup p.R568Efs*26 | Frame Shift Ins (INS) | VAF 17/94 reads (18%) | catalogued as rs751548647; called by mutect2, varscan2
- CIR1 | c.294G>A p.W98* | Nonsense Mutation (SNP) | VAF 17/96 reads (18%) | catalogued as COSV100564974; called by muse, mutect2, varscan2
- CKM | c.502G>T p.E168* | Nonsense Mutation (SNP) | VAF 3/43 reads (7%) | catalogued as COSV55532964, COSV99675543; called by muse, mutect2
- CMIP | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV101606997; called by muse, mutect2, varscan2
- CNGB3 | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs752014086, COSV60695307; called by muse, mutect2
- COPB2 | c.2647G>A p.D883N | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.202); catalogued as COSV100169068; called by muse, mutect2, varscan2
- CREB3L3 | c.1028G>A p.G343D | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV99314146; called by muse, mutect2, varscan2
- CRKL | c.871G>A p.V291I | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs1001709647, COSV62883193; called by muse, mutect2, varscan2
- CRPPA | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752817129, CM123240, COSV67904405; called by muse, mutect2, varscan2
- CYP20A1 | c.903dup p.L302Ifs*3 | Frame Shift Ins (INS) | VAF 24/107 reads (22%) | catalogued as rs778884333; called by mutect2, varscan2
- DCX | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as COSV100576253; called by muse, mutect2, varscan2
- DDAH1 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.419); catalogued as COSV99394850; called by muse, mutect2, varscan2
- DDIAS | c.479T>C p.L160P | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758893827, COSV100231186; called by muse, mutect2
- DHPS | c.83G>A p.S28N | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99269599; called by muse, mutect2
- DHX57 | c.3368C>T p.A1123V | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99769478; called by muse, mutect2, varscan2
- DLG5 | c.644G>A p.R215K | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.036); catalogued as COSV100967467; called by muse, mutect2
- DLGAP1 | c.989del p.P330Hfs*79 | Frame Shift Del (DEL) | VAF 13/54 reads (24%) | catalogued as COSV59781013; called by mutect2, pindel, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 27/70 reads (39%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK8 | c.2303C>T p.A768V | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs140779178; called by muse, mutect2, varscan2
- DYNC1H1 | c.7117A>G p.M2373V | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV100794853; called by muse, mutect2, varscan2
- DYNC1H1 | c.13412C>T p.A4471V | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100794854; called by muse, mutect2, varscan2
- E2F4 | c.53A>G p.H18R | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.871); catalogued as COSV100103872; called by muse, mutect2
- ECT2L | c.1541T>C p.L514P | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100871941; called by muse, mutect2, varscan2
- EFL1 | c.2944G>A p.A982T | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.721); catalogued as COSV99186915; called by muse, mutect2
- ELK3 | c.525dup p.V176Rfs*14 | Frame Shift Ins (INS) | VAF 12/50 reads (24%) | catalogued as rs769175197; called by mutect2, varscan2
- ELOVL4 | c.266T>C p.L89P | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100876260; called by muse, mutect2, varscan2
- ENPP6 | c.1063G>A p.G355S | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763177717, COSV99698776; called by muse, mutect2, varscan2
- EPHX4 | c.515dup p.M173Hfs*12 | Frame Shift Ins (INS) | VAF 25/59 reads (42%) | catalogued as rs765115164; called by mutect2, varscan2
- ERBB4 | c.3028G>A p.E1010K | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV61507216; called by muse, mutect2, varscan2
- ESRP1 | c.492T>A p.Y164* | Nonsense Mutation (SNP) | VAF 19/86 reads (22%) | catalogued as COSV100619299; called by muse, mutect2, varscan2
- EVI5L | c.511C>T p.Q171* | Nonsense Mutation (SNP) | VAF 15/73 reads (21%) | catalogued as COSV99563127; called by muse, mutect2, varscan2
- FAM222B | c.691C>T p.R231W | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.832); catalogued as rs770786658, COSV57929274; called by muse, mutect2, varscan2
- FAM47C | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.18); catalogued as rs1556331634, COSV100792526; called by muse, mutect2, varscan2
- FAT4 | c.5356A>G p.S1786G | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); catalogued as COSV100628562; called by muse, mutect2, varscan2
- FBLN2 | c.532C>A p.H178N | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV99851877; called by muse, mutect2, varscan2
- FBXO10 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 63/96 reads (66%) | SIFT tolerated (0.13); PolyPhen benign (0.204); catalogued as COSV99446636; called by muse, mutect2, varscan2
- FBXW11 | c.584G>A p.R195K | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as COSV99440420; called by muse, mutect2, varscan2
- FCRL2 | c.1193C>T p.T398I | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.087); catalogued as rs767149698, COSV100829909; called by muse, mutect2, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 18/74 reads (24%) | catalogued as rs777980924; called by mutect2, pindel, varscan2
- FIGN | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.74); PolyPhen benign (0.014); catalogued as rs1443984992, COSV100292329; called by muse, mutect2
- FLG | c.4253C>T p.P1418L | Missense Mutation (SNP) | VAF 86/461 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0.019); catalogued as rs1415090178, COSV100911555; called by muse, mutect2, varscan2
- FLT1 | c.3244G>A p.V1082M | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142586121; called by muse, mutect2, varscan2
- FNDC3A | c.1673C>T p.T558I (on ENST00000492622 / NM_001079673.2; = p.T502I on NM_014923.5) | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs765669733, COSV101256718; called by muse, mutect2, varscan2
- FOLR3 | c.16C>T p.Q6* | Nonsense Mutation (SNP) | VAF 24/56 reads (43%) | catalogued as COSV100281789, COSV61530070; called by muse, mutect2, varscan2
- FOXN1 | c.1748C>T p.P583L | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.059); catalogued as COSV56881236, COSV99881278; called by muse, mutect2, varscan2
- GABRA4 | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201606797, COSV51933718; called by muse, mutect2, varscan2
- GATA3 | c.431del p.G144Afs*51 | Frame Shift Del (DEL) | VAF 14/61 reads (23%) | catalogued as COSV60516711; called by mutect2, pindel, varscan2
- GBX1 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV52549632; called by muse, mutect2
- GEMIN2 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 45/49 reads (92%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.472); catalogued as COSV99158212; called by muse, mutect2, varscan2
- GGT6 | c.836C>A p.A279E (on ENST00000574154 / NM_001122890.3; = p.A247E on NM_153338.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); catalogued as rs145161228, COSV99626088; called by muse, varscan2
- GPR158 | c.2204C>T p.T735I | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV100893502; called by muse, mutect2, varscan2
- GPRC6A | c.2543C>T p.A848V | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV100114358; called by muse, mutect2, varscan2
- GPRC6A | c.2302A>G p.I768V | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as COSV100114359; called by mutect2, varscan2
- GRAP2 | c.776G>A p.R259Q | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs1164470654, COSV59995487; called by muse, mutect2, varscan2
- GSE1 | c.366del p.V123Wfs*2 | Frame Shift Del (DEL) | VAF 36/114 reads (32%) | catalogued as rs754199513; called by mutect2, varscan2
- GUCA1B | c.568C>T p.L190F | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV99273977; called by muse, mutect2
- HCFC1 | c.1570C>T p.R524W | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV60073660; called by muse, mutect2, varscan2
- HDAC11 | c.831C>T p.G277= | Splice Region (SNP) | VAF 16/35 reads (46%) | catalogued as rs1379194373, COSV55475053; called by muse, mutect2, varscan2
- HELB | c.1421G>C p.S474T | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99921900; called by muse, mutect2, varscan2
- HJURP | c.1327C>T p.R443W | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs750138498, COSV64978654; called by muse, mutect2, varscan2
- HMCN1 | c.15786G>A p.M5262I | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.542); catalogued as COSV99629056; called by muse, mutect2, varscan2
- HMG20A | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.51); PolyPhen benign (0.045); catalogued as COSV100287762; called by muse, mutect2, varscan2
- IDH2 | c.220C>T p.H74Y | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1163791289, COSV100343773; called by muse, mutect2, varscan2
- IGF1R | c.2612C>T p.S871L | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1198959559, COSV51277320; called by muse, mutect2, varscan2
- IGLV4-69 | c.146G>A p.S49N | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as rs768843405; called by muse, mutect2, varscan2
- IKZF4 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs971684447, COSV100009103; called by muse, mutect2, varscan2
- IMMT | c.1267A>G p.K423E | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.141); catalogued as COSV99607260; called by muse, mutect2, varscan2
- INTS6 | c.884C>T p.S295L | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs764593870, COSV60877286; called by muse, mutect2, varscan2
- ITGB5 | c.410C>A p.P137H | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99950663; called by muse, mutect2, varscan2
- ITPRIPL1 | c.731dup p.Q245Tfs*32 (on ENST00000439118 / NM_001008949.3; = p.Q253Tfs*32 on NM_178495.6) | Frame Shift Ins (INS) | VAF 12/77 reads (16%) | catalogued as rs749417016; called by mutect2, pindel, varscan2
- KALRN | c.7183G>A p.G2395R (on ENST00000360013 / NM_001024660.4; = p.G698R on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs150398770, COSV99361941; called by muse, mutect2, varscan2
- KCNE5 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1260266181, COSV100927704; called by muse, mutect2, varscan2
- KIAA0895L | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs774014417, COSV51782571; called by muse, mutect2, varscan2
- KIF19 | c.2189C>T p.P730L | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV100739063; called by muse, mutect2, varscan2
- KLHL12 | c.437A>G p.N146S | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1457771904, COSV100766158; called by muse, mutect2
- KMT2D | c.14355G>A p.M4785I | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.344); catalogued as rs1011898577, COSV99981474; called by muse, mutect2, varscan2
- KRTAP1-1 | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100092105; called by muse, mutect2, varscan2
- LDLRAD4 | c.211A>G p.I71V | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs1264139988, COSV100762154; called by muse, mutect2, varscan2
- LENG8 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV100457490; called by muse, mutect2
- LILRB3 | c.528del p.F177Sfs*10 | Frame Shift Del (DEL) | VAF 21/30 reads (70%) | catalogued as rs1555885460; called by mutect2, varscan2
- LMBR1 | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.639); catalogued as COSV100626675; called by muse, mutect2, varscan2
- LRCH3 | c.293C>A p.P98H | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100605080; called by muse, mutect2
- LRRC2 | c.683G>A p.S228N | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99947413; called by muse, mutect2, varscan2
- LRRN2 | c.1211A>G p.Q404R | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as COSV100912835; called by muse, mutect2
- LTBP1 | c.4964C>G p.T1655R (on ENST00000404816 / NM_206943.4; = p.T1329R on NM_000627.4) | Missense Mutation (SNP) | VAF 44/172 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.136); catalogued as COSV99698258; called by muse, mutect2, varscan2
- MAP3K1 | c.1151A>G p.E384G | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV101266738; called by muse, mutect2, varscan2
- MATN2 | c.131C>T p.T44M | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.828); catalogued as rs775304395, COSV99646271; called by muse, mutect2, varscan2
- MAZ | c.1262G>A p.C421Y | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99361118; called by muse, mutect2, varscan2
- MCEE | c.419del p.K140Rfs*6 | Frame Shift Del (DEL) | VAF 9/31 reads (29%) | catalogued as rs776473131; called by mutect2, varscan2
- MET | c.308G>A p.S103N | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs768675699, COSV100577209; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MGAT4C | c.674A>G p.D225G | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100152925; called by muse, mutect2, varscan2
- MICAL3 | c.5327G>T p.R1776M | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.34); catalogued as rs1370390884, COSV101490861; called by muse, mutect2, varscan2
- MICAL3 | c.1828C>G p.L610V | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99261464; called by muse, mutect2, varscan2
- MID2 | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.085); catalogued as COSV99464680; called by muse, mutect2, varscan2
- MIER3 | c.768G>C p.K256N | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs768937291, COSV100423540; called by muse, mutect2, varscan2
- MS4A10 | c.46C>T p.L16F | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs767169631, COSV100382287; called by muse, mutect2, varscan2
- MSR1 | c.1147G>A p.V383I | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.09); catalogued as rs766405850, COSV100027928, COSV50542362; called by muse, mutect2, varscan2
- MTMR3 | c.2903A>T p.D968V | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.034); catalogued as COSV100070803; called by muse, mutect2
- MYCL | c.337C>A p.L113I (on ENST00000372816 / NM_001033081.3; = p.L143I on NM_005376.5) | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100862334; called by muse, mutect2
- MYH2 | c.3990A>C p.K1330N | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV99820086; called by muse, mutect2, varscan2
- MYO16 | c.3860G>A p.S1287N | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV100696691; called by muse, mutect2
- MYO18B | c.3509C>T p.A1170V | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs754177763, COSV100123590; called by muse, mutect2, varscan2
- MYO5A | c.2027G>T p.R676M | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100697626; called by muse, mutect2, varscan2
- MYO6 | c.3883A>G p.K1295E (on ENST00000369981; = p.K1285E on NM_004999.4) | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.234); catalogued as COSV100889347; called by muse, mutect2, varscan2
- NARS2 | c.1163C>T p.T388M | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769693580, COSV55251431; called by muse, mutect2, varscan2
- NENF | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 13/303 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as COSV65341035; called by muse, mutect2
- NPNT | c.748G>T p.G250* | Nonsense Mutation (SNP) | VAF 6/64 reads (9%) | catalogued as COSV99975082; called by muse, mutect2, varscan2
- NSA2 | c.292C>T p.R98* | Nonsense Mutation (SNP) | VAF 7/21 reads (33%) | catalogued as COSV99713667; called by muse, mutect2, varscan2
- NUGGC | c.1359G>C p.K453N | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.094); catalogued as COSV58432865; called by muse, mutect2
- NXPE3 | c.1228C>T p.P410S | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99839948; called by muse, mutect2, varscan2
- OR10J1 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.055); catalogued as rs758895629, COSV71129817; called by muse, mutect2, varscan2
- OSBPL2 | c.1180G>T p.E394* (on ENST00000313733 / NM_144498.4; = p.E382* on NM_014835.4) | Nonsense Mutation (SNP) | VAF 13/39 reads (33%) | catalogued as COSV100569249; called by muse, mutect2, varscan2
- OTUD5 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.918); catalogued as COSV50235664; called by muse, mutect2, varscan2
- PAXBP1 | c.967A>G p.I323V | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.066); catalogued as COSV99269270; called by muse, mutect2
- PCED1A | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100642880; called by muse, mutect2
- PCLO | c.7325del p.K2442Sfs*2 | Frame Shift Del (DEL) | VAF 13/48 reads (27%) | catalogued as COSV61618667; called by mutect2, varscan2
- PCNX4 | c.347A>G p.H116R | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.067); catalogued as rs1454401309, COSV100470288; called by muse, mutect2, varscan2
- PDE4DIP | c.3257C>T p.T1086I | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.522); catalogued as COSV100519068; called by muse, mutect2, varscan2
- PHC2 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs201814819; called by muse, mutect2, varscan2
- PHF3 | c.3944C>A p.P1315H | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100013322; called by muse, mutect2, varscan2
- PHKG1 | c.76C>A p.L26M | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52081783; called by muse, mutect2, varscan2
- PHLDB1 | c.1280G>A p.R427Q | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.46); catalogued as rs184032736, COSV100616524, COSV61880439; called by muse, mutect2, varscan2
- PKM | c.17G>C p.S6T | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.046); catalogued as COSV100064809; called by muse, mutect2, varscan2
- PLAGL1 | c.787C>A p.L263I | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.04); catalogued as COSV99394386; called by muse, mutect2, varscan2
- PLB1 | c.4366G>A p.V1456M | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.001); catalogued as COSV100578601; called by muse, mutect2, varscan2
- PLXNB1 | c.2321C>T p.A774V | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1157154658, COSV99602457, COSV99602815; called by muse, mutect2, varscan2
- PPARGC1A | c.1640G>A p.C547Y | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.731); catalogued as COSV99337879; called by muse, mutect2, varscan2
- PPM1H | c.1462C>T p.R488W | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs752870905, COSV57371693; called by muse, mutect2, varscan2
- PTPN23 | c.3859A>G p.M1287V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as COSV99650547; called by muse, mutect2
- R3HCC1L | c.702T>G p.I234M | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); catalogued as COSV100107328; called by muse, mutect2, varscan2
- RABEP2 | c.1559C>T p.T520I | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.077); catalogued as COSV100707009; called by muse, mutect2, varscan2
- RAD51AP1 | c.208del p.R70Dfs*21 (on ENST00000228843 / NM_001130862.2; = p.R70Gfs*4 on NM_006479.5) | Frame Shift Del (DEL) | VAF 6/39 reads (15%) | catalogued as rs745353960; called by mutect2, pindel, varscan2
- RAMP1 | c.135G>T p.Q45H | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV99614680; called by muse, mutect2, varscan2
- RAPSN | c.397T>G p.F133V | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.124); catalogued as COSV100100191; called by muse, mutect2, varscan2
- RBM45 | c.1149del p.A384Lfs*7 (on ENST00000616198 / NM_001365579.1; = p.A382Lfs*7 on NM_152945.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 21/66 reads (32%) | catalogued as rs749563266; called by mutect2, varscan2
- RIMS4 | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1277817424, COSV65719391; called by muse, mutect2, varscan2
- RPL10L | c.311C>T p.S104F | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as COSV100022561, COSV53559384; called by muse, mutect2, varscan2
- RTL5 | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV65454741; called by mutect2, varscan2
- SCNN1D | c.1288G>T p.G430* (on ENST00000338555; = p.G594* on NM_001130413.4) | Nonsense Mutation (SNP) | VAF 6/54 reads (11%) | catalogued as COSV100329883; called by mutect2, varscan2
- SHROOM3 | c.5033A>G p.Q1678R | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.877); catalogued as COSV99934287; called by muse, mutect2, varscan2
- SIAH3 | c.308C>T p.T103M | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV68552106; called by muse, mutect2, varscan2
- SLAMF7 | c.54A>G p.T18= | Splice Region (SNP) | VAF 31/194 reads (16%) | catalogued as rs1181069033, COSV100833277, COSV63563169; called by muse, mutect2, varscan2
- SLC25A11 | c.833T>G p.L278R | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99337369; called by muse, mutect2, varscan2
- SLC27A3 | c.1600C>T p.P534S (on ENST00000271857; = p.P406S on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.113); catalogued as COSV99669925; called by muse, mutect2, varscan2
- SLC30A10 | c.695A>C p.K232T | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); catalogued as COSV100751500; called by muse, mutect2, varscan2
- SLC35D3 | c.1163C>T p.A388V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.033); catalogued as rs1333773017, COSV100090504; called by muse, mutect2, varscan2
- SLC38A7 | c.242dup p.V82Rfs*31 | Frame Shift Ins (INS) | VAF 29/95 reads (31%) | catalogued as rs755556671; called by mutect2, pindel, varscan2
- SNAI1 | c.547G>A p.G183R | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.095); catalogued as rs544515729, COSV99723922; called by muse, mutect2, varscan2
- SREBF1 | c.1287del p.S430Rfs*268 | Frame Shift Del (DEL) | VAF 14/95 reads (15%) | catalogued as rs769275980; called by mutect2, pindel, varscan2
- STRADA | c.1091C>T p.P364L (on ENST00000336174 / NM_001363786.1; = p.P327L on NM_153335.6) | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs775610521, COSV99368570; called by muse, mutect2, varscan2
- STXBP2 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 45/61 reads (74%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as rs763174109, COSV99657133; called by muse, mutect2, varscan2
- SUPT5H | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.169); catalogued as COSV100781900; called by muse, mutect2, varscan2
- TBL1X | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.429); catalogued as COSV54283329; called by muse, mutect2, varscan2
- TESPA1 | c.1043C>T p.A348V (on ENST00000316577 / NM_001098815.3; = p.A210V on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV100345221; called by muse, mutect2, varscan2
- TG | c.4575G>T p.Q1525H | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.687); catalogued as rs532885276, COSV55079568, COSV99600792; called by muse, mutect2, varscan2
- TICAM1 | c.1925del p.P642Hfs*50 | Frame Shift Del (DEL) | VAF 22/97 reads (23%) | catalogued as COSV50235787; called by mutect2, pindel, varscan2
- TMEM120A | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV99951413; called by muse, mutect2, varscan2
- TMEM199 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99134775; called by muse, mutect2, varscan2
- TNRC6C | c.911C>T p.A304V | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.036); catalogued as COSV100049974; called by muse, mutect2, varscan2
- TRIM4 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.092); catalogued as rs777573423, COSV62469327; called by muse, mutect2, varscan2
- TRPC6 | c.1745-1G>A p.X582_splice | Splice Site (SNP) | VAF 6/22 reads (27%) | catalogued as COSV100723598; called by muse, mutect2
- TTI1 | c.3176A>G p.H1059R | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV100989635; called by muse, mutect2, varscan2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 14/58 reads (24%) | catalogued as rs763254614; called by mutect2, varscan2
- TTLL2 | c.241G>A p.G81R | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.011); catalogued as COSV99514418, COSV99514687; called by muse, mutect2, varscan2
- TTN | c.34283C>T p.P11428L (on ENST00000591111; = p.P12491L on NM_001267550.2) | Missense Mutation (SNP) | VAF 26/95 reads (27%) | PolyPhen benign (0.009); catalogued as rs750941307, COSV59899854; called by muse, mutect2, varscan2
- TUBA3C | c.884G>A p.C295Y | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); catalogued as COSV101262790; called by muse, mutect2
- UBQLNL | c.761C>A p.P254Q | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.06); catalogued as COSV100974365; called by muse, mutect2, varscan2
- UROC1 | c.2003G>A p.R668Q | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV99331424; called by muse, mutect2, varscan2
- USP34 | c.10336G>T p.D3446Y | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.281); catalogued as rs369630143, COSV63724874; called by muse, mutect2, varscan2
- VANGL2 | c.962G>A p.G321D | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as COSV100925566; called by muse, mutect2
- VASH2 | c.926G>A p.R309Q (on ENST00000517399 / NM_001301056.2; = p.R265Q on NM_024749.5) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.56); catalogued as rs1182716628, COSV99663533; called by muse, mutect2, varscan2
- VPS39 | c.1996A>G p.M666V (on ENST00000348544 / NM_001301138.2; = p.M655V on NM_015289.5) | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs1177213291, COSV100529180; called by muse, mutect2, varscan2
- VWA3A | c.806T>C p.M269T | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.079); catalogued as COSV101233115; called by muse, varscan2
- WDR92 | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.21); catalogued as rs1212685050, COSV99718285; called by muse, mutect2, varscan2
- YTHDF3 | c.211C>T p.L71F | Missense Mutation (SNP) | VAF 56/233 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101572387; called by muse, mutect2, varscan2
- ZFP36L1 | c.284del p.G95Afs*53 | Frame Shift Del (DEL) | VAF 5/33 reads (15%) | catalogued as COSV60544219; called by mutect2, pindel
- ZMYM4 | c.1290del p.K430Nfs*6 | Frame Shift Del (DEL) | VAF 15/36 reads (42%) | catalogued as rs755663477, COSV58913572; called by mutect2, varscan2
- ZNF205 | c.596G>C p.G199A | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.025); catalogued as rs915147778, COSV99530387; called by muse, mutect2, varscan2
- ZNF235 | c.99C>A p.Y33* | Nonsense Mutation (SNP) | VAF 44/150 reads (29%) | catalogued as COSV52156047, COSV99349443; called by muse, mutect2, varscan2
- ZNF28 | c.1784C>T p.A595V | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as COSV100354480; called by muse, mutect2, varscan2
- ZNF543 | c.1294T>C p.F432L | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100386761; called by muse, mutect2, varscan2
- ZNF597 | c.398_399del p.S133* | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | catalogued as rs773002034; called by pindel, varscan2
- ZNF672 | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs374647323; called by muse, mutect2, varscan2
- ZNRF3 | c.2645G>A p.C882Y (on ENST00000544604 / NM_001206998.2; = p.C782Y on NM_032173.3) | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs1449558490, COSV100238436; called by muse, mutect2, varscan2
- AFF2 | c.82del p.R28Gfs*30 | Frame Shift Del (DEL) | VAF 8/83 reads (10%) | called by mutect2, pindel
- C1R | c.344del p.G115Efs*14 (on ENST00000536053 / NM_001354346.2; = p.G101Efs*14 on NM_001733.7) | Frame Shift Del (DEL) | VAF 22/74 reads (30%) | called by mutect2, pindel, varscan2
- CCDC78 | c.635C>T p.A212V | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- CNTN4 | c.2715del p.G906Efs*14 | Frame Shift Del (DEL) | VAF 15/46 reads (33%) | called by mutect2, pindel, varscan2
- CWF19L2 | c.2261del p.L754Wfs*5 | Frame Shift Del (DEL) | VAF 5/45 reads (11%) | called by pindel, varscan2
- DHDDS | c.517del p.V173Wfs*31 | Frame Shift Del (DEL) | VAF 18/41 reads (44%) | called by mutect2, pindel, varscan2
- DONSON | c.326del p.L109* | Frame Shift Del (DEL) | VAF 9/43 reads (21%) | called by mutect2, pindel, varscan2
- GCNA | c.221+2T>C p.X74_splice | Splice Site (SNP) | VAF 17/100 reads (17%) | called by muse, mutect2, varscan2
- KIR2DL1 | c.878A>G p.D293G | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- LAD1 | c.1138_1146dup p.P380_K382dup | In Frame Ins (INS) | VAF 18/142 reads (13%) | called by mutect2, varscan2
- LRP6 | c.1949dup p.N650Kfs*3 | Frame Shift Ins (INS) | VAF 13/74 reads (18%) | called by mutect2, pindel, varscan2
- LRRC36 | c.1949del p.N650Tfs*4 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | called by mutect2, pindel, varscan2
- NOMO1 | c.653A>T p.N218I | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.057); called by mutect2, varscan2
- PIP5KL1 | c.1059del p.Y353* (on ENST00000388747 / NM_001135219.2; = p.Y150* on NM_173492.1) | Frame Shift Del (DEL) | VAF 53/172 reads (31%) | called by mutect2, pindel, varscan2
- PPARGC1B | c.408del p.S137Afs*69 | Frame Shift Del (DEL) | VAF 14/61 reads (23%) | called by mutect2, pindel, varscan2
- PRDX4 | c.694G>T p.V232F | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2
- RFX5 | c.56del p.P19Qfs*28 | Frame Shift Del (DEL) | VAF 22/101 reads (22%) | called by mutect2, pindel, varscan2
- SPATA2L | c.643del p.R215Efs*102 | Frame Shift Del (DEL) | VAF 19/89 reads (21%) | called by mutect2, pindel, varscan2
- SUPT20HL1 | c.2147C>T p.T716I | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.116); called by muse, mutect2
- TCF7 | c.402dup p.S135Lfs*57 | Frame Shift Ins (INS) | VAF 23/92 reads (25%) | called by mutect2, pindel, varscan2
- TP53INP1 | c.156_158del p.E52del | In Frame Del (DEL) | VAF 6/70 reads (9%) | called by pindel, varscan2
- TRBV19 | c.38T>A p.L13H | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.068); called by muse, mutect2
- TRPV4 | c.235del p.V79Cfs*50 | Frame Shift Del (DEL) | VAF 16/67 reads (24%) | called by mutect2, pindel, varscan2
- ZNF280C | c.1887del p.D630Ifs*26 | Frame Shift Del (DEL) | VAF 33/132 reads (25%) | called by mutect2, pindel, varscan2
- ABCA7 | c.1605G>A p.P535= | Silent (SNP) | VAF 34/83 reads (41%) | catalogued as COSV54028946; called by muse, mutect2, varscan2
- ACOX3 | c.618C>T p.H206= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as rs746063263, COSV100711949; called by muse, mutect2, varscan2
- ACTRT1 | c.927G>A p.G309= | Silent (SNP) | VAF 7/90 reads (8%) | catalogued as COSV100947587, COSV64419609; called by muse, mutect2
- AL645922.1 | c.546T>C p.T182= | Silent (SNP) | VAF 10/125 reads (8%) | catalogued as COSV100191063; called by muse, mutect2
- ANGPT4 | c.346C>T p.L116= | Silent (SNP) | VAF 5/86 reads (6%) | catalogued as rs1279977526, COSV101124727; called by muse, mutect2
- ANKRD10 | c.906C>T p.C302= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV99941125; called by muse, mutect2, varscan2
- ARC | c.1041G>A p.Q347= | Silent (SNP) | VAF 20/112 reads (18%) | catalogued as rs139437874; called by muse, mutect2, varscan2
- ARMH3 | c.198T>C p.L66= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as COSV100228905; called by muse, mutect2, varscan2
- ARR3 | c.180C>T p.G60= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as COSV57204735; called by muse, mutect2, varscan2
- ARV1 | c.258G>A p.Q86= | Silent (SNP) | VAF 6/123 reads (5%) | catalogued as COSV100048430; called by muse, mutect2
- ATP13A1 | c.2094C>T p.H698= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as COSV52289744, COSV99366124; called by muse, mutect2, varscan2
- ATRX | c.6624T>C p.Y2208= | Silent (SNP) | VAF 33/85 reads (39%) | catalogued as COSV100970722; called by muse, mutect2, varscan2
- ATXN10 | c.865C>T p.L289= | Silent (SNP) | VAF 8/134 reads (6%) | catalogued as COSV53295481, COSV99426324; called by muse, mutect2
- BEND5 | c.792C>T p.P264= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as rs377372975, COSV65718651; called by muse, mutect2, varscan2
- BMI1 | c.837G>A p.V279= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as COSV64958877; called by muse, mutect2, varscan2
- C11orf68 | c.378G>A p.S126= (on ENST00000530188; = p.S167= on NM_031450.4) | Silent (SNP) | VAF 34/76 reads (45%) | catalogued as rs374355629; called by muse, mutect2, varscan2
- C2orf49 | c.480G>A p.V160= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV99307475; called by muse, mutect2, varscan2
- C4orf17 | c.345T>C p.S115= | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as COSV100430905; called by muse, mutect2, varscan2
- CCDC134 | c.282C>T p.P94= | Silent (SNP) | VAF 27/51 reads (53%) | catalogued as COSV55389136; called by muse, mutect2, varscan2
- CCDC141 | c.1815G>A p.S605= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs150141190, COSV99837537; called by muse, mutect2, varscan2
- CCL16 | c.72G>A p.Q24= | Silent (SNP) | VAF 12/51 reads (24%) | called by muse, mutect2, varscan2
- CCNF | c.771A>G p.E257= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV99563582; called by muse, mutect2
- CKMT1B | c.954T>A p.S318= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV100294563; called by muse, varscan2
- CLDN25 | c.72C>A p.S24= | Silent (SNP) | VAF 4/53 reads (8%) | catalogued as COSV101493600; called by muse, mutect2
- CORO7 | c.1653C>A p.A551= | Silent (SNP) | VAF 32/98 reads (33%) | catalogued as COSV99227638; called by muse, mutect2, varscan2
- CREBBP | c.2931G>T p.S977= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as COSV99269973; called by muse, mutect2, varscan2
- CRTAC1 | c.1797C>T p.N599= | Silent (SNP) | VAF 29/100 reads (29%) | catalogued as rs372101559; called by muse, mutect2, varscan2
- CSH2 | c.597C>T p.V199= | Silent (SNP) | VAF 79/301 reads (26%) | catalogued as rs909532810, COSV61080399; called by muse, mutect2, varscan2
- CSMD3 | c.1221C>T p.D407= | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as COSV52107792, COSV99833807; called by muse, mutect2, varscan2
- CTNNA1 | c.747G>A p.Q249= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV100242711; called by muse, mutect2, varscan2
- DCLRE1C | c.1353T>C p.D451= (on ENST00000378278 / NM_001350965.2; = p.D336= on NM_022487.4) | Silent (SNP) | VAF 32/53 reads (60%) | catalogued as rs1564366591, COSV100543088; called by muse, mutect2, varscan2
- DNAH8 | c.9564C>T p.D3188= | Silent (SNP) | VAF 16/97 reads (16%) | catalogued as COSV100545125; called by muse, mutect2, varscan2
- DPYSL4 | c.183C>T p.H61= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as rs749104221, COSV100633942; called by muse, mutect2, varscan2
- DYSF | c.1614C>A p.P538= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs180970066, COSV99246902; ClinVar: likely benign / uncertain significance; called by muse, varscan2
- ERCC2 | c.2077C>T p.L693= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as COSV101228887; called by muse, mutect2
- FFAR4 | c.882C>T p.S294= | Silent (SNP) | VAF 6/127 reads (5%) | catalogued as COSV101012271; called by muse, mutect2
- FRMD4B | c.2508C>T p.N836= | Silent (SNP) | VAF 11/97 reads (11%) | catalogued as rs762223223, COSV101273444; called by muse, mutect2, varscan2
- FST | c.570G>T p.V190= | Silent (SNP) | VAF 24/87 reads (28%) | catalogued as COSV99887173; called by muse, mutect2, varscan2
- GDAP2 | c.699A>G p.S233= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as rs749133878, COSV101031989; called by mutect2, varscan2
- HINT1 | c.318G>A p.Q106= | Silent (SNP) | VAF 19/96 reads (20%) | catalogued as COSV100401151; called by muse, mutect2, varscan2
- HSPG2 | c.7128G>A p.K2376= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV101020671; called by muse, mutect2
- IL27RA | c.1614C>A p.T538= | Silent (SNP) | VAF 27/104 reads (26%) | catalogued as COSV99652133; called by muse, mutect2, varscan2
- KCNH7 | c.630C>A p.P210= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as COSV100035845; called by muse, mutect2, varscan2
- KCNQ3 | c.1536C>A p.I512= | Silent (SNP) | VAF 50/166 reads (30%) | catalogued as COSV101196107; called by muse, mutect2, varscan2
- KCTD19 | c.903G>A p.A301= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as rs768982567, COSV100430908; called by muse, mutect2, varscan2
- KRT6B | c.606C>A p.G202= | Silent (SNP) | VAF 22/189 reads (12%) | catalogued as COSV99360700; called by muse, mutect2, varscan2
- LASP1 | c.312G>A p.T104= | Silent (SNP) | VAF 22/92 reads (24%) | catalogued as rs1444156861, COSV100530362; called by muse, mutect2, varscan2
- LTBP2 | c.2142G>A p.L714= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as COSV56206380; called by muse, mutect2, varscan2
- MEAK7 | c.945G>A p.K315= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV100640396; called by muse, mutect2, varscan2
- MED16 | c.2157G>T p.L719= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV99515606; called by muse, mutect2, varscan2
- MET | c.3075G>A p.Q1025= | Silent (SNP) | VAF 29/79 reads (37%) | catalogued as COSV100577210; called by muse, mutect2, varscan2
- MITF | c.1533C>T p.S511= (on ENST00000448226 / NM_006722.3; = p.S411= on NM_000248.4) | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV100096905; called by muse, mutect2, varscan2
- MUC5B | c.14934C>T p.D4978= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as COSV101500303; called by muse, mutect2, varscan2
- MX1 | c.966C>T p.C322= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as COSV99912623; called by muse, mutect2, varscan2
- MYH3 | c.1803T>A p.P601= | Silent (SNP) | VAF 28/103 reads (27%) | catalogued as COSV99878199; called by muse, mutect2, varscan2
- MYPN | c.255C>T p.Y85= | Silent (SNP) | VAF 32/65 reads (49%) | catalogued as rs1445478783, COSV62732727; called by muse, mutect2, varscan2
- MYRF | c.1803C>T p.T601= (on ENST00000278836 / NM_001127392.3; = p.T592= on NM_013279.4) | Silent (SNP) | VAF 5/63 reads (8%) | catalogued as COSV99607054; called by muse, mutect2
- NID1 | c.1005C>T p.R335= | Silent (SNP) | VAF 20/88 reads (23%) | catalogued as rs751558873, COSV99937474; called by muse, mutect2, varscan2
- NRK | c.4158C>T p.N1386= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV99687701; called by muse, mutect2, varscan2
- NXPH3 | c.525C>T p.C175= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as rs1052590062, COSV100165514; called by muse, mutect2, varscan2
- OR11H1 | c.121C>T p.L41= | Silent (SNP) | VAF 25/219 reads (11%) | catalogued as rs760506096, COSV99421787; called by muse, mutect2, varscan2
- OR2V2 | c.840G>T p.T280= | Silent (SNP) | VAF 36/95 reads (38%) | catalogued as COSV100080104, COSV60315109; called by muse, mutect2, varscan2
- PARP10 | c.69C>T p.P23= | Silent (SNP) | VAF 55/109 reads (50%) | catalogued as rs782276875, COSV100477788, COSV100478013; called by muse, mutect2, varscan2
- PCDHB8 | c.1677G>A p.S559= | Silent (SNP) | VAF 52/408 reads (13%) | catalogued as rs782449653, COSV50754171; called by muse, mutect2, varscan2
- PHF3 | c.873A>G p.K291= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV100013321; called by muse, mutect2, varscan2
- PIP5K1A | c.444C>T p.R148= (on ENST00000368888 / NM_001135638.2; = p.R135= on NM_003557.3) | Silent (SNP) | VAF 10/216 reads (5%) | catalogued as COSV100576611; called by muse, mutect2
- PKHD1L1 | c.10764A>G p.A3588= | Silent (SNP) | VAF 22/106 reads (21%) | catalogued as rs764628541, COSV101006097; called by muse, mutect2, varscan2
- PRDM8 | c.2061G>A p.S687= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs530807635, COSV100325119; called by muse, mutect2, varscan2
- PRRX1 | c.465C>T p.A155= | Silent (SNP) | VAF 22/146 reads (15%) | catalogued as rs1446279126, COSV99509677; called by muse, mutect2, varscan2
- PSMB7 | c.628C>T p.L210= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as COSV99412869; called by muse, mutect2, varscan2
- REPS2 | c.1461C>G p.T487= | Silent (SNP) | VAF 27/75 reads (36%) | catalogued as COSV100381116; called by muse, mutect2, varscan2
- RIMBP2 | c.1023C>T p.R341= | Silent (SNP) | VAF 26/168 reads (15%) | catalogued as rs1417273262, COSV99899438; called by muse, mutect2, varscan2
- SAR1B | c.345T>C p.L115= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as COSV101284164; called by muse, mutect2, varscan2
- SI | c.2091C>T p.P697= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV100015477; called by muse, mutect2, varscan2
- SIGLEC1 | c.198G>A p.Q66= | Silent (SNP) | VAF 5/98 reads (5%) | catalogued as COSV99165044; called by muse, mutect2
- SIK3 | c.4080G>A p.Q1360= (on ENST00000445177 / NM_001366686.2; = p.Q1318= on NM_025164.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/80 reads (43%) | catalogued as COSV99407974; called by muse, mutect2, varscan2
- SLC4A3 | c.3219C>A p.P1073= | Silent (SNP) | VAF 16/100 reads (16%) | catalogued as COSV99812796; called by muse, mutect2, varscan2
- SLC8A1 | c.2010G>T p.P670= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as rs137879982, COSV100245989; called by muse, mutect2, varscan2
- SLC9A3R1 | c.696C>T p.D232= | Silent (SNP) | VAF 7/134 reads (5%) | catalogued as COSV99380026; called by muse, mutect2
- SLC9C2 | c.2199G>A p.V733= | Silent (SNP) | VAF 16/107 reads (15%) | catalogued as COSV100876745; called by muse, mutect2, varscan2
- SNAPC4 | c.1461T>C p.S487= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV100047184; called by muse, mutect2, varscan2
- SRMS | c.625C>T p.L209= | Silent (SNP) | VAF 5/54 reads (9%) | catalogued as COSV99421345; called by muse, mutect2, varscan2
- SYNE1 | c.6123A>G p.K2041= (on ENST00000367255 / NM_182961.4; = p.K2048= on NM_033071.3) | Silent (SNP) | VAF 9/131 reads (7%) | catalogued as COSV99563420; called by muse, mutect2
- TACC3 | c.438A>G p.P146= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as COSV100508705, COSV57602707; called by muse, mutect2, varscan2
- TIMM44 | c.960G>A p.E320= | Silent (SNP) | VAF 29/84 reads (35%) | catalogued as COSV99564037; called by muse, mutect2, varscan2
- TRPA1 | c.3267C>T p.D1089= | Silent (SNP) | VAF 32/174 reads (18%) | catalogued as rs779660540, COSV100084095; called by muse, mutect2, varscan2
- TSNAXIP1 | c.1437G>A p.Q479= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV99535071; called by muse, mutect2, varscan2
- TTBK2 | c.1842A>G p.S614= | Silent (SNP) | VAF 33/77 reads (43%) | catalogued as rs376681856, COSV99141504; called by muse, mutect2, varscan2
- VSTM4 | c.301C>T p.L101= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV100039303; called by muse, mutect2, varscan2
- ZFP36 | c.585C>T p.G195= (on ENST00000594442; = p.G189= on NM_003407.5) | Silent (SNP) | VAF 41/129 reads (32%) | catalogued as COSV99953800; called by muse, mutect2, varscan2
- ZNF366 | c.468G>A p.K156= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV100574253; called by muse, mutect2, varscan2
- ZNF696 | c.444G>T p.S148= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV100350505; called by muse, mutect2, varscan2
- ZP4 | c.1335A>G p.S445= | Silent (SNP) | VAF 16/109 reads (15%) | catalogued as COSV100850675; called by muse, mutect2, varscan2
- AC024940.1 | n.4129G>C | RNA (SNP) | VAF 10/302 reads (3%) | called by muse, mutect2
- AC024940.1 | n.3299G>A | RNA (SNP) | VAF 18/324 reads (6%) | called by muse, mutect2
- ACHE | c.1723+182_1723+184del | Intron (DEL) | VAF 8/41 reads (20%) | catalogued as rs772244054; called by pindel, varscan2
- RN7SL484P | chr15:99792315 C>T | 3'Flank (SNP) | VAF 7/84 reads (8%) | called by muse, mutect2
- SSPOP | n.3502T>C | RNA (SNP) | VAF 16/85 reads (19%) | catalogued as COSV100022492; called by muse, mutect2, varscan2
- SSPOP | n.7664G>A | RNA (SNP) | VAF 18/67 reads (27%) | catalogued as COSV100947379; called by muse, mutect2, varscan2
- SYNJ2 | c.3744+901G>A | Intron (SNP) | VAF 29/132 reads (22%) | catalogued as rs188000207, COSV62897597; called by muse, mutect2, varscan2
- TTN | c.34265-4662del | Intron (DEL) | VAF 44/223 reads (20%) | called by mutect2, pindel, varscan2
